Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042795-09A.3 (aliquot TARGET-15-SJMPAL042795-09A.3-01D) from TARGET case TARGET-15-SJMPAL042795, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.5 years (200 days).
Specimen TARGET-15-SJMPAL042795-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1aff003b-0bdb-431b-938b-cd6af1f8b043.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042795-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042795-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/180d654b-c5e7-4ccc-b39a-3c019881bda0

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMKK1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.522); catalogued as rs113610926, COSV50126685; called by muse, mutect2, varscan2
- CDK3 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV100043835; called by muse, mutect2
- PIK3CD | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV63128987; called by muse, mutect2, varscan2
- SMIM14 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV55902914; called by muse, mutect2
- GCC2 | c.3300C>A p.D1100E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by mutect2, varscan2
- TBCD | c.2234C>A p.P745Q | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.056); called by muse, mutect2
- TMCO4 | c.1265-1G>T p.X422_splice | Splice Site (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- APP | c.711G>A p.V237= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as rs770301922; called by muse, varscan2
- RGPD4 | c.3345G>A p.T1115= | Silent (SNP) | VAF 79/123 reads (64%) | catalogued as rs1170361941; called by muse, mutect2, varscan2
- TUBB8 | c.21G>A p.T7= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1228342230, COSV59116768; called by muse, mutect2, varscan2
- TUBB8P7 | n.649delinsTA | RNA (INS) | VAF 6/24 reads (25%) | called by pindel, varscan2*
